Somatic mutation profile of tumor specimen MMRF_1131_2_BM_CD138pos (aliquot MMRF_1131_2_BM_CD138pos_T2_KBS5U_L05855) from MMRF case MMRF_1131, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 41.5 years (15,160 days).
Specimen MMRF_1131_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c9c3caf-f1af-477c-8b03-e2994997d978.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1131_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1131_2_PB_Whole_C1_KBS5U_L05764; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/421a4d00-fccb-456f-b161-6d51de4c977d

The open-access MAF lists 93 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 37, Missense Mutation 31, Silent 10, Intron 6, 5'UTR 3, Frame Shift Del 2, 3'Flank 2, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUX2 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.255); catalogued as rs200610249, COSV55637478; called by muse, mutect2, varscan2
- ECEL1 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1042062974, COSV58813972; called by muse, mutect2, varscan2
- IGHV2-70 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs370193821; called by muse, varscan2
- IGHV2-70D | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1388922516; called by muse, varscan2
- IGLL5 | c.28T>A p.C10S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as rs1343384174; called by muse, mutect2, varscan2
- IGLL5 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.08); catalogued as rs538723125, COSV73251010, COSV73251135, COSV73251305; called by muse, mutect2, varscan2
- IGLV3-1 | c.313T>A p.Y105N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs574479963; called by muse, varscan2
- LUC7L2 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV99055132; called by muse, mutect2, varscan2
- PDE7B | c.237C>A p.F79L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1374026692; called by muse, mutect2, varscan2
- PGBD5 | c.470C>T p.T157M (on ENST00000525115; = p.T226M on NM_001258311.2) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.515); catalogued as rs779019200, COSV100358585; called by muse, mutect2, varscan2
- RBPJL | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.212); catalogued as rs747490348, COSV59212980; called by muse, mutect2, varscan2
- TOR1B | c.992C>G p.S331W | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV52212657; called by muse, mutect2, varscan2
- ZHX2 | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.453); catalogued as COSV58715007; called by muse, mutect2, varscan2
- AC023055.1 | c.1293T>G p.S431R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ANKRD26 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CHD5 | c.3758G>C p.S1253T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- CLEC11A | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- COL15A1 | c.2369G>T p.G790V | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COQ7 | c.539A>G p.E180G | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); called by muse, mutect2
- DDR2 | c.1284G>C p.M428I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EIF4A1 | c.281T>A p.I94N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- FOXL3 | c.692G>T p.W231L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- HMCN1 | c.3640G>A p.D1214N | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IGHV2-70D | c.191A>C p.K64T | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, varscan2
- IQSEC1 | c.1975A>G p.I659V | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- IRF4 | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAKMIP3 | c.660A>C p.R220S | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIF16B | c.2222A>G p.Y741C | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRGPRF | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- MTCH2 | c.730_731del p.M244Gfs*39 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- RWDD4 | c.526del p.V176* | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- SECISBP2 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- TALDO1 | c.407A>G p.K136R | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TRIM69 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DCTN2 | c.519G>T p.L173= (on ENST00000548249 / NM_001261413.2; = p.L178= on NM_006400.4) | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, varscan2
- IGHE | c.171C>T p.A57= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs782132756; called by muse, mutect2, varscan2
- IGHV2-70 | c.273C>T p.S91= | Silent (SNP) | VAF 18/21 reads (86%) | catalogued as rs115694694; called by muse, varscan2
- IGHV2-70 | c.129C>T p.F43= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as rs548066677; called by muse, varscan2
- IGHV2-70D | c.78T>A p.S26= | Silent (SNP) | VAF 26/44 reads (59%) | called by muse, varscan2
- IPO5 | c.3054C>T p.D1018= | Silent (SNP) | VAF 32/39 reads (82%) | called by muse, mutect2, varscan2
- NOX3 | c.1554C>T p.F518= | Silent (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- OR8H1 | c.633C>T p.I211= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as rs747106722; called by muse, mutect2, varscan2
- RPIA | c.21C>T p.F7= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as rs1332323186; called by muse, mutect2, varscan2
- SLITRK3 | c.1479G>A p.R493= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV53850984, COSV53853819; called by muse, mutect2, varscan2
- ALDH3B2 | c.*196G>A | 3'UTR (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- AP3S2 | chr15:89894326 T>A | 5'Flank (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2
- ASTN1 | c.*3061del | 3'UTR (DEL) | VAF 18/95 reads (19%) | catalogued as rs1209629516; called by mutect2, pindel, varscan2
- ATP8B1 | c.*1776T>A | 3'UTR (SNP) | VAF 20/51 reads (39%) | called by muse, mutect2, varscan2
- B3GALT5 | c.*988C>A | 3'UTR (SNP) | VAF 42/69 reads (61%) | catalogued as rs866139521; called by muse, mutect2, varscan2
- C8orf48 | c.*264T>C | 3'UTR (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- CASKIN2 | c.1680+57C>A | Intron (SNP) | VAF 24/42 reads (57%) | catalogued as rs1001677464; called by muse, mutect2, varscan2
- CD300E | c.*398G>C | 3'UTR (SNP) | VAF 4/10 reads (40%) | catalogued as rs939998567; called by muse, varscan2
- CDK5R1 | c.*1606C>G | 3'UTR (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- CDK5R2 | c.*175G>C | 3'UTR (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- CLDN1 | c.*1928G>A | 3'UTR (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- EPHA4 | c.*91del | 3'UTR (DEL) | VAF 4/43 reads (9%) | catalogued as COSV56037088; called by mutect2, pindel
- ETFDH | c.*551A>G | 3'UTR (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- FNBP1 | c.*902G>A | 3'UTR (SNP) | VAF 11/26 reads (42%) | catalogued as rs1021309658; called by muse, mutect2, varscan2
- GCSAM | c.*2055C>G | 3'UTR (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- GNG4 | c.*272A>C | 3'UTR (SNP) | VAF 27/119 reads (23%) | called by muse, mutect2, varscan2
- HIBCH | c.*207C>T | 3'UTR (SNP) | VAF 30/52 reads (58%) | called by muse, mutect2, varscan2
- IGHV3-21 | c.-7A>C | 5'UTR (SNP) | VAF 23/54 reads (43%) | catalogued as rs782068951; called by muse, mutect2, varscan2
- JMJD1C | c.*237T>C | 3'UTR (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- KLHL3 | c.*3810G>T | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- KRTAP2-4 | c.*81T>G | 3'UTR (SNP) | VAF 18/44 reads (41%) | catalogued as COSV101224319, COSV67458553; called by muse, varscan2
- LBH | c.*374G>A | 3'UTR (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- LCA5 | c.*1114T>G | 3'UTR (SNP) | VAF 34/61 reads (56%) | called by muse, mutect2, varscan2
- LRRC27 | chr10:132377738 G>C | 3'Flank (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- NAP1L2 | c.*102A>T | 3'UTR (SNP) | VAF 19/19 reads (100%) | called by muse, mutect2, varscan2
- NDUFB3 | c.*17C>A | 3'UTR (SNP) | VAF 28/54 reads (52%) | called by muse, mutect2, varscan2
- PRDM6 | c.*419C>A | 3'UTR (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- PTCH1 | c.*2671T>C | 3'UTR (SNP) | VAF 29/54 reads (54%) | called by muse, mutect2, varscan2
- PTGES3 | c.*12A>G | 3'UTR (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- RASGEF1C | c.1084-854del | Intron (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel
- RBFOX2 | c.*5330T>C | 3'UTR (SNP) | VAF 23/50 reads (46%) | catalogued as COSV101314084; called by muse, mutect2, varscan2
- RIMBP2 | c.*2541T>C | 3'UTR (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- RPA2 | c.*14G>T | 3'UTR (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- RXRB | c.-109C>A | 5'UTR (SNP) | VAF 34/62 reads (55%) | called by muse, mutect2, varscan2
- SEMA6D | c.*1027_*1028del | 3'UTR (DEL) | VAF 4/45 reads (9%) | catalogued as rs1491072323; called by pindel, varscan2*
- SH2D4B | chr10:80644259 C>T | 3'Flank (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- SPR | c.*516C>T | 3'UTR (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- SRD5A3 | c.-51G>A | 5'UTR (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- STXBP5L | c.*2791G>A | 3'UTR (SNP) | VAF 11/28 reads (39%) | catalogued as rs551747700; called by muse, mutect2, varscan2
- TAPT1 | c.*1896A>C | 3'UTR (SNP) | VAF 36/69 reads (52%) | called by muse, mutect2, varscan2
- TLCD5 | c.*224G>A | 3'UTR (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- TMED5 | c.*2002G>A | 3'UTR (SNP) | VAF 25/59 reads (42%) | catalogued as rs1037524680; called by muse, mutect2, varscan2
- TPO | c.2748+546C>T | Intron (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- TSKS | c.1623-48C>T | Intron (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- UBE2E3 | c.*365G>C | 3'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- UVSSA | c.*8293del | 3'UTR (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- WDR24 | c.685+45C>T | Intron (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- WDR27 | c.*43G>A | 3'UTR (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- WIPF3 | c.1428+477A>T | Intron (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
